Somatic mutation profile of tumor specimen TARGET-30-PALFPI-01A (aliquot TARGET-30-PALFPI-01A-01W) from TARGET case TARGET-30-PALFPI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 3.2 years (1,152 days).
Specimen TARGET-30-PALFPI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d436819d-fe83-4282-9eaf-c4ca184050a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALFPI-10A (Blood Derived Normal), aliquot TARGET-30-PALFPI-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/108c6473-df03-4214-a419-1a9acf9cdec6

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1463177829, COSV59384882; called by muse, mutect2, varscan2
- DENND4B | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780558094, COSV63412117, COSV63412251; called by muse, mutect2, varscan2
- EP400 | c.8380C>T p.Q2794* | Nonsense Mutation (SNP) | VAF 60/150 reads (40%) | catalogued as COSV57787037; called by muse, mutect2, varscan2
- GOLGB1 | c.2157C>A p.S719R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV61471309; called by muse, mutect2, varscan2
- GTF3C4 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64646196; called by muse, mutect2, varscan2
- IGF2BP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs1024617698, COSV51736242; called by muse, mutect2, varscan2
- IKZF4 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100009457, COSV56271810; called by muse, mutect2, varscan2
- IL1B | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1195068613, COSV54523331; called by muse, mutect2, varscan2
- ITGB4 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52333066; called by muse, mutect2, varscan2
- MSI2 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52361239, COSV99402528; called by muse, mutect2
- MUC13 | c.1251C>T p.D417= | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as COSV60701391; called by muse, mutect2, varscan2
- NLRP5 | c.2362C>G p.L788V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs777722243, COSV66767558; called by muse, mutect2, varscan2
- OR1C1 | c.97T>G p.C33G | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as rs199881737; called by muse, mutect2, varscan2
- OR1E1 | c.499T>G p.C167G | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV59459843; called by muse, mutect2, varscan2
- SLC19A1 | c.1276C>A p.L426I | Missense Mutation (SNP) | VAF 56/497 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60758055; called by muse, mutect2, varscan2
- SORL1 | c.3697G>T p.V1233F | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.72); PolyPhen benign (0.098); catalogued as COSV52763198; called by muse, mutect2, varscan2
- TSC1 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 241/2066 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV53773701; called by muse, varscan2
- USP43 | c.2276C>A p.S759Y | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53307216; called by muse, mutect2, varscan2
- ZNF442 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1237171990, COSV54422903, COSV54423438; called by muse, mutect2, varscan2
- ASXL3 | c.2336dup p.S780Lfs*6 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- COL4A2 | c.3844G>T p.D1282Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYP4X1 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); called by muse, mutect2
- GCC2 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- KIAA0100 | c.5667G>T p.Q1889H | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOP9 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- OR8K3 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); called by muse, mutect2
- PRRC2B | c.1602G>T p.Q534H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- THOC5 | c.1743del p.Q581Hfs*4 | Frame Shift Del (DEL) | VAF 63/184 reads (34%) | called by mutect2, pindel*, varscan2*
- VRTN | c.1250C>G p.T417R | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CACNA1A | c.1141C>A p.R381= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs773593740, COSV100801034, COSV64212946; called by muse, mutect2, varscan2
- CSPG4 | c.381G>A p.G127= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57901833; called by muse, mutect2
- DMXL1 | c.5517C>T p.S1839= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV60721296; called by muse, mutect2, varscan2
- KRT33A | c.213G>T p.L71= | Silent (SNP) | VAF 15/331 reads (5%) | called by muse, mutect2
- METTL22 | c.1056C>T p.Y352= | Silent (SNP) | VAF 56/443 reads (13%) | catalogued as rs750338300; called by muse, mutect2, varscan2
- MUC17 | c.6066C>A p.G2022= | Silent (SNP) | VAF 69/139 reads (50%) | catalogued as COSV60304128; called by muse, mutect2, varscan2
- SPTAN1 | c.321C>T p.N107= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- TMED4 | c.399C>A p.L133= | Silent (SNP) | VAF 22/387 reads (6%) | called by muse, mutect2
- ZNF446 | c.213G>A p.L71= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1377367102, COSV52182575; called by muse, mutect2
- ZNF883 | c.204T>G p.P68= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV71309254; called by muse, mutect2, varscan2
